Somatic mutation profile of tumor specimen MP2PRT-PAVFUF-TBP1-A (aliquot MP2PRT-PAVFUF-TBP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAVFUF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,455 days).
Specimen MP2PRT-PAVFUF-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) daffb9b6-3a46-4271-ae58-602c4eb0dfd1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVFUF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVFUF-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b345b98-f89b-403d-8f39-e7afca2494fd

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 3, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 77/622 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- NF1 | c.5867T>C p.L1956P (on ENST00000358273 / NM_001042492.3; = p.L1935P on NM_000267.3) | Missense Mutation (SNP) | VAF 20/281 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM1311488, COSV62215975; called by muse, mutect2
- BCL6 | c.267_268insTTA p.F89_M90insL | In Frame Ins (INS) | VAF 84/358 reads (23%) | called by mutect2, pindel*, varscan2
- IGFL3 | c.291G>C p.L97F | Missense Mutation (SNP) | VAF 160/413 reads (39%) | SIFT tolerated (0.41); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- DLST | c.909C>T p.D303= | Silent (SNP) | VAF 102/344 reads (30%) | catalogued as rs373738787; called by muse, mutect2, varscan2
- GTF3C1 | c.6228C>T p.D2076= | Silent (SNP) | VAF 30/960 reads (3%) | catalogued as rs1212678193, COSV62243405, COSV62245442; called by muse, mutect2
- JPH3 | c.1347C>T p.T449= | Silent (SNP) | VAF 222/920 reads (24%) | catalogued as rs148323380; called by muse, varscan2
- NPAS4 | c.1836T>C p.P612= | Silent (SNP) | VAF 173/698 reads (25%) | called by muse, mutect2, varscan2
- PLCE1 | c.2283G>A p.S761= | Silent (SNP) | VAF 100/415 reads (24%) | catalogued as rs1024454830; called by muse, mutect2, varscan2
